CCDI case PBCHTN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Stomach.
https://portal.gdc.cancer.gov/cases/a8574227-20b1-46ff-88b9-e5fbb621f848

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Gastrointestinal stromal tumor, NOS: ICD-O-3 morphology code: 8936/3; Tissue or organ of origin: Gastric antrum; Age at diagnosis: 17.7 years (6,451 days).

Biospecimens (3 samples)
- Samples 0DS52K, 0DSMY1 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSMYE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
